Somatic mutation profile of tumor specimen MP2PRT-PAVPPX-TMP1-A (aliquot MP2PRT-PAVPPX-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVPPX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,035 days).
Specimen MP2PRT-PAVPPX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d4d5cd8-0c9f-4140-8bff-743d0a1ec405.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPPX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPPX-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed6a62d0-f7ad-415a-98b0-c79f329801a7

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, In Frame Ins 1, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 32/472 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- COL1A2 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 66/532 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs773985005, COSV51964997; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NRAP | c.3682A>T p.S1228C (on ENST00000359988 / NM_001322945.2; = p.S1193C on NM_006175.4) | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs147917122; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBI1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56147107; called by muse, mutect2
- OR10C1 | c.368G>A p.R123H (on ENST00000622521; = p.R121H on NM_013941.3) | Missense Mutation (SNP) | VAF 37/894 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs770659210; called by muse, mutect2
- TTN | c.58566C>G p.I19522M (on ENST00000591111; = p.I12098M on NM_003319.4) | Missense Mutation (SNP) | VAF 15/354 reads (4%) | PolyPhen benign (0.246); catalogued as COSV59928878; called by muse, mutect2
- XKR6 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 108/774 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs768684995; called by muse, mutect2, varscan2
- ZNF337 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 63/469 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV53320808; called by muse, mutect2, varscan2
- CENPO | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CLASP2 | c.4516G>A p.D1506N (on ENST00000359576; = p.D1505N on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CRYBG2 | c.2347C>T p.H783Y | Missense Mutation (SNP) | VAF 77/589 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX55 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 89/576 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GAS2L3 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 16/368 reads (4%) | called by muse, mutect2
- HRC | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 65/482 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- HYAL4 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 140/461 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- KIAA2012 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDLRAD4 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 55/445 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MAGI3 | c.90_91insCTTGGC p.G30_A31insLG | In Frame Ins (INS) | VAF 119/784 reads (15%) | called by pindel, varscan2
- NAF1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 81/456 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS21 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 19/591 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2
- PTK7 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SEMG2 | c.389A>T p.H130L | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SIGLEC7 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.314); called by muse, mutect2
- SPATA31E1 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- STARD10 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 83/615 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.45907G>A p.E15303K (on ENST00000591111; = p.E7879K on NM_003319.4) | Missense Mutation (SNP) | VAF 25/348 reads (7%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- TUBA8 | c.621del p.A208Pfs*84 | Frame Shift Del (DEL) | VAF 59/469 reads (13%) | called by mutect2, pindel, varscan2
- CLDN15 | c.210C>A p.A70= | Silent (SNP) | VAF 14/367 reads (4%) | called by muse, mutect2
- ERBB3 | c.2397G>A p.V799= | Silent (SNP) | VAF 74/465 reads (16%) | catalogued as COSV57246613; called by muse, varscan2
- SRCIN1 | c.132C>T p.F44= | Silent (SNP) | VAF 107/861 reads (12%) | called by muse, mutect2, varscan2
- RFX4 | c.44-7463C>T | Intron (SNP) | VAF 42/323 reads (13%) | catalogued as rs752551451; called by muse, mutect2, varscan2
